APOLLO case AP-YCYR — Proteogenomic analysis of tumors from young women with breast cancer (APOLLO-BRCA-1)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/96291bde-7708-479c-836c-ad139a2db62f

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Infiltrating ductular carcinoma: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS.

Biospecimens (2 samples)
- Sample AP-YCYR-6Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
- Sample AP-YCYR-NU: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: OCT.
